Surgical pathology report (de-identified scan), TCGA case TCGA-AO-A125, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site MSKCC, specimen TCGA-AO-A125-01A (Primary Tumor).

[page 1 of 6]
Clinical Diagnosis and History:
Multicentric DCIS and invasive cancer of left breast (mass at 12:00 and DCIS on core biopsy 9:00).

Specimens Submitted:

- 1: SP: Sentinel node #1, level 1, left axilla
- 2: SP: Sentinel node #2, level 1, left axilla
- 3: SP: Sentinel node #3, level 1, left axilla
- 4: SP: Sentinel node #4, level 1, left axilla
- 5: SP: Non-sentinel node, left axilla
- 6: SP: Left total mastectomy (

DIAGNOSIS:

- 1) LYMPH NODE, SENTINEL #1, LEVEL I, LEFT AXILLA; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- DEEPER LEVEL RECUTS AND SPECIAL STAINS HAVE BEEN ORDERED.
THE RESULTS WILL BE REPORTED IN AN ADDENDUM.
- 2) LYMPH NODE, SENTINEL #2, LEVEL I, LEFT AXILLA; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- DEEPER LEVEL RECUTS AND SPECIAL STAINS HAVE BEEN ORDERED.
THE RESULTS WILL BE REPORTED IN AN ADDENDUM.
- 3) LYMPH NODE, SENTINEL #3, LEVEL I, LEFT AXILLA; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- DEEPER LEVEL RECUTS AND SPECIAL STAINS HAVE BEEN ORDERED.
THE RESULTS WILL BE REPORTED IN AN ADDENDUM.
- 4) LYMPH NODE, SENTINEL #4, LEFT AXILLA; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- DEEPER LEVEL RECUTS AND SPECIAL STAINS HAVE BEEN ORDERED.
THE RESULTS WILL BE REPORTED IN AN ADDENDUM.
- 5) LYMPH NODE, NON-SENTINEL, LEFT AXILLA; EXCISION:
ONE BENIGN LYMPH NODE (0/1).
- 6) BREAST, LEFT; TOTAL MASTECTOMY:
- IN-SITU AND INVASIVE PAPILLARY CARCINOMA.
- THE TUMOR MEASURES 3 CM IN GREATEST DIMENSION. SINCE THE TUMOR GROWS AS LARGE BROAD FRONTS, IT IS NOT POSSIBLE TO ASSESS THE EXTENT OF INVASION.
- DUCTAL CARCINOMA IN-SITU (DCIS) IS ALSO IDENTIFIED, SOLID/CRIBRIFORM TYPES, WITH INTERMEDIATE NUCLEAR GRADE.
- THE INVASIVE CARCINOMA IS LOCATED IN THE CENTRAL/ SUPERIOR

** Continued on next page **

PATH
REPORT
11

1CD-0-3

carcinoma, papillary, NOS (invasive) 8050/3
Site: breast, NOS C50.9 lw 10/22/11

HPA Discrepancy		
Dis-/Synchronous Primary Nodul		
	lw 10/22/11	

[page 2 of 6]
AREA.

- THE DCIS IS LOCATED IN THE CENTRAL/SUPERIOR AREA AND MEDIAL ASPECT AT THE PREVIOUS BIOPSY SITE.
- NO INVOLVEMENT OF THE NIPPLE BY EITHER IN-SITU OR INVASIVE CARCINOMA IS IDENTIFIED.
- CALCIFICATIONS ARE PRESENT IN THE IN-SITU CARCINOMA AND IN BENIGN BREAST PARENCHYMA.
- NO VASCULAR INVASION IS NOTED.
- INVASIVE CARCINOMA IS 0.3 CM FROM THE NEAREST (SUPERIOR) MARGIN.
- DUCTAL CARCINOMA IN-SITU IS 0.3 CM FROM THE NEAREST (SUPERIOR) MARGIN.
- NO SKIN INVOLVEMENT BY CARCINOMA IS IDENTIFIED.
- THE NON-NEOPLASTIC BREAST TISSUE IS UNREMARKABLE.
- THE NON-NEOPLASTIC BREAST TISSUE SHOWS BIOPSY SITE CHANGES, FIBROCYSTIC CHANGES, BENIGN PAPILLOMAS AND SCLEROSING ADENOSIS.
- RESULTS OF SPECIAL STAINS (ER, PR, HER2-NEU) WILL BE REPORTED AS AN ADDENDUM.

NOTE: DR. BROGI HAS REVIEWED SELECTED SLIDES AND CONCURS.

** Report Electronically Signed Out **

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Stain/Procedure Name	Result	Comment
AE1:AE3	NEGATIVE	
KERATIN (CAM5.2)	NEGATIVE	
NEGATIVE CONTROL		
IMMUNO RECUT		
NEGATIVE CONTROL		* Canceled
IMMUNO RECUT		* Canceled
AE1:AE3	NEGATIVE	
KERATIN (CAM5.2)	NEGATIVE	
NEGATIVE CONTROL		
IMMUNO RECUT		
NEGATIVE CONTROL		
IMMUNO RECUT		* Canceled
AE1:AE3	NEGATIVE	
KERATIN (CAM5.2)	NEGATIVE	
NEGATIVE CONTROL		
IMMUNO RECUT		
NEGATIVE CONTROL		* Canceled
IMMUNO RECUT		* Canceled
AE1:AE3	NEGATIVE	
KERATIN (CAM5.2)	NEGATIVE	

PATH
REPORT
11

** Continued on next page **

[page 3 of 6]
NEGATIVE CONTROL		
IMMUNO RECUT		
NEGATIVE CONTROL		* Canceled
IMMUNO RECUT		* Canceled
ESTROGEN RECEPTOR	POSITIVE	
PROGESTERONE RECEPTOR	POSITIVE	
HER2-C	NEGATIVE	INTENSITY 0
NEGATIVE CONTROL		
IMMUNO RECUT		
SYNAPTOPHYSIN		
CHROMOGRANIN		
MIB-1 (Ki-67)		
RECUT ADDITIONAL HE		
CALPONIN		
NEGATIVE CONTROL		* Canceled
IMMUNO RECUT		* Canceled
NEGATIVE CONTROL		
IMMUNO RECUT		
NEGATIVE CONTROL FOR HER2		

3

Gross Description:

1) The specimen is received fresh for frozen section diagnosis, labeled "Sentinel node #1, level I, left axilla". It consists of a lymph node measuring 2 x 1.5 x 0.5 cm. The entire specimen is submitted in one cassette.

Summary of sections:

FSC - frozen section control

2) The specimen is received fresh for frozen section diagnosis, labeled "Sentinel node #2, level I, left axilla". It consists of a lymph node measuring 0.7 x 0.7 x 0.4 cm. The entire specimen is submitted in one cassette.

Summary of sections:

FSC - frozen section control

3) The specimen is received fresh for frozen section diagnosis, labeled "Sentinel node #3, level I, left axilla". It consists of a lymph node measuring 2 x 1.5 x 0.7 cm. The entire specimen is submitted in one cassette.

Summary of sections:

FSC - frozen section control

PATH
REPORT
11

** Continued on next page **

[page 4 of 6]
4) The specimen is received fresh for frozen section diagnosis, labeled "Sentinel node #4, level I, left axilla". It consists of a lymph node measuring 2.5 x 0.6 x 0.5 cm. The entire specimen is submitted in one cassette.

Summary of sections:

FSC - frozen section control

4

5) The specimen is received fresh for frozen section diagnosis, labeled "Non-sentinel node, left axilla". It consists of a lymph node measuring 2.5 x 1.5 x 0.6 cm. The entire specimen is submitted in one cassette.

Summary of sections:

FSC - frozen section control

6) The specimen is received fresh, labeled "Left Total Mastectomy, Stitch Marks Axillary Aspect". It consists of a total mastectomy measuring 20.0 x 15.0 x 6.0 cm. The skin is brown-black and measures 17.0 x 7.0 cm. Areola nipple complex is unremarkable and measures 3.5 cm in diameter. No scars were grossly identified. The cut sections reveals a mass measuring 3.0 x 2.5 x 2.0 cm. This mass is located 0.5 cm from the superior margin. This is the closest margin. The cut sections through the other areas of the breast shows fibrocystic changes. Sections from the lateral upper and lower, medial upper and lower quadrants are at least 1.0 cm from the closest deep margin. The tumor is submitted entirely. The representative sections are also submitted.

Summary of Sections:

N - nipple
TSM - tumor superior margin
T - tumor
LL - lateral lower quadrant
LU - lateral upper quadrant
ML - medial lower quadrant
MU - medial upper quadrant
SK - skin

Summary of Sections:

Part	Sect.	Site	Blocks	Pieces	All
1	FSC		1	1	Y
2	FSC		1	1	Y
3	FSC		1	1	Y
4	FSC		1	1	Y
5	FSC		1	1	Y
6	LL		2	M	
	LU		3	M	
	ML		2	M	
	MU		2	M	

PATH
REPORT
11

** Continued on next page **

[page 5 of 6]
N	1	M
SK	1	M
T	3	M
TSM	2	M

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: BENIGN.
PERMANENT DIAGNOSIS: SAME.
- 2) FROZEN SECTION DIAGNOSIS: BENIGN.
PERMANENT DIAGNOSIS: SAME.
- 3) FROZEN SECTION DIAGNOSIS: BENIGN.
PERMANENT DIAGNOSIS: SAME.
- 4) FROZEN SECTION DIAGNOSIS: BENIGN.
PERMANENT DIAGNOSIS: SAME.
- 5) FROZEN SECTION DIAGNOSIS: BENIGN.
PERMANENT DIAGNOSIS: SAME.

ADDENDUM:

** SIGNED OUT **

ADDENDUM REPORT

SITE: LEFT BREAST, #6

ER-ICA: POSITIVE

PR-ICA: POSITIVE

HER2/NEU (Hercep Test): NEGATIVE (STAINING INTENSITY 0)

CONTROLS ARE SATISFACTORY.

** Report Electronically Signed Out **

ADDENDUM:

** SIGNED OUT **

ADDENDUM REPORT

PATH
REPORT
11

** Continued on next page **

[page 6 of 6]
SITE: SENTINEL LYMPH NODES, LEFT AXILLA
PARTS #1, 2, 3, 4

ADDITIONAL HE STAINED SECTIONS AND IMMUNOHISTOCHEMICAL STAINS
FOR CYTOKERATINS (AE1:AE3 AND CAM5.2) SHOW NO EVIDENCE OF
METASTATIC TUMOR.

** Report Electronically Signed Out **

** End of Report **

PATH
REPORT
11

Source: NCI Genomic Data Commons file 7839321e-a6c4-4481-81aa-69d48c811ca1 (TCGA-AO-A125.AE348902-0573-4A57-BBD6-037FA2AF1872.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).